Gene-level copy-number profile of specimen HCM-CSHL-0510-D13-85A from HCMI case HCM-CSHL-0510-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 59.1 years (21,570 days).
Specimen HCM-CSHL-0510-D13-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32e05508-0da2-43d8-81a3-b95338af4388.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0510-D13-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/3b22abab-b15e-49ce-bd2d-3115f46c451f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 169; copy number 2: 55,667; copy number 3: 2,561.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
